Somatic mutation profile of tumor specimen TCGA-DD-AAVZ-01A (aliquot TCGA-DD-AAVZ-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 38.3 years (14,005 days).
Specimen TCGA-DD-AAVZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 678e1c08-7862-4958-b7e7-fb4a2a284348.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVZ-10A (Blood Derived Normal), aliquot TCGA-DD-AAVZ-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c8d7ad0-a5f3-4215-b9f0-c6951e8e66b9

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 16, Frame Shift Ins 4, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773712027, COSV99522023; called by muse, mutect2, varscan2
- ADGRB3 | c.2984T>G p.V995G | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53238827, COSV99486076; called by muse, mutect2, varscan2
- ADORA3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV53984934; called by muse, mutect2, varscan2
- ARR3 | c.837C>A p.C279* | Nonsense Mutation (SNP) | VAF 146/195 reads (75%) | catalogued as COSV52103481, COSV99333774; called by muse, mutect2, varscan2
- BEST3 | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99876291; called by muse, mutect2, varscan2
- BRCA1 | c.1972A>G p.M658V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs55932871, COSV100524668; called by muse, mutect2, varscan2
- BRWD1 | c.6927A>C p.L2309F | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100313718; called by muse, mutect2, varscan2
- C2CD3 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV100487022; called by muse, mutect2, varscan2
- CHRNB3 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 181/272 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV99251323; called by muse, mutect2, varscan2
- CSMD3 | c.9478A>G p.T3160A (on ENST00000297405 / NM_001363185.1; = p.T2991A on NM_052900.3) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV99840044; called by muse, mutect2, varscan2
- DDX59 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV100494618; called by muse, mutect2, varscan2
- EIF5 | c.994A>T p.K332* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV99384928; called by muse, mutect2, varscan2
- ELAPOR2 | c.1387G>A p.D463N (on ENST00000450689 / NM_001142749.3; = p.D296N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as rs1438684087, COSV99789111; called by muse, mutect2, varscan2
- ELF2 | c.286A>G p.I96V (on ENST00000379550 / NM_001331036.2; = p.I36V on NM_006874.4) | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs1241203866, COSV99643059; called by muse, mutect2, varscan2
- FMN2 | c.3764C>G p.P1255R | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as COSV100146211; called by muse, mutect2, varscan2
- GPR158 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV100893964; called by muse, mutect2, varscan2
- ITGB5 | c.614A>C p.Y205S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as COSV56146739, COSV99950902; called by muse, mutect2, varscan2
- NIPA2 | c.98dup p.L35Pfs*21 | Frame Shift Ins (INS) | VAF 31/74 reads (42%) | catalogued as rs145147241; called by mutect2, varscan2
- OTOGL | c.4982_4983insC p.T1662Yfs*13 (on ENST00000547103; = p.T1653Yfs*13 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 40/109 reads (37%) | catalogued as COSV100087508; called by mutect2, pindel, varscan2
- PDCD7 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV99200148; called by muse, mutect2, varscan2
- PRKCZ | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66066316; called by muse, mutect2, varscan2
- RAB3GAP1 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV99921408; called by muse, mutect2, varscan2
- SCN10A | c.5077G>A p.G1693R | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761742228, COSV101479468; called by muse, mutect2, varscan2
- SLC12A2 | c.1814C>G p.A605G | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99321326; called by muse, mutect2, varscan2
- SNAPC4 | c.4093C>T p.R1365W | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs372472067; called by muse, mutect2, varscan2
- SPRY3 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100249424; called by muse, mutect2, varscan2
- UTY | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100229728, COSV100229905; called by muse, mutect2, varscan2
- ZNF248 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.555); catalogued as COSV100627654; called by muse, mutect2, varscan2
- ZNF581 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.521); catalogued as COSV99553185; called by muse, mutect2, varscan2
- AXIN1 | c.1663_1667del p.T555Qfs*34 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | called by mutect2, pindel, varscan2
- GXYLT1 | c.573dup p.L192Tfs*3 | Frame Shift Ins (INS) | VAF 86/281 reads (31%) | called by mutect2, pindel, varscan2
- KIF14 | c.4699_4700del p.V1567Pfs*9 | Frame Shift Del (DEL) | VAF 175/345 reads (51%) | called by mutect2, pindel, varscan2
- NFIA | c.582dup p.S195Qfs*5 | Frame Shift Ins (INS) | VAF 76/156 reads (49%) | called by mutect2, pindel, varscan2
- ASB2 | c.192C>T p.A64= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100279440; called by muse, mutect2, varscan2
- CELA2A | c.696C>T p.H232= | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as rs201638508; called by muse, mutect2, varscan2
- DENND2D | c.1410G>A p.V470= | Silent (SNP) | VAF 66/139 reads (47%) | catalogued as COSV100718743; called by muse, mutect2, varscan2
- FAM47C | c.1272C>G p.S424= | Silent (SNP) | VAF 38/51 reads (75%) | catalogued as COSV100792794; called by muse, mutect2, varscan2
- FN1 | c.5604C>T p.Y1868= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs1255686643, COSV60550033; called by muse, mutect2, varscan2
- HMCN1 | c.1173T>A p.I391= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV99632159; called by muse, mutect2, varscan2
- IGBP1 | c.39C>A p.P13= | Silent (SNP) | VAF 46/61 reads (75%) | catalogued as COSV100643018, COSV60555508; called by muse, mutect2, varscan2
- LOXL4 | c.1140C>T p.C380= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs771955268, COSV53257693; called by muse, mutect2, varscan2
- OR8H1 | c.903T>C p.I301= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as COSV100477234; called by muse, mutect2, varscan2
- PCDHB5 | c.1611C>T p.S537= | Silent (SNP) | VAF 71/165 reads (43%) | catalogued as COSV99169249; called by muse, mutect2, varscan2
- PDAP1 | c.306C>T p.D102= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs148987199; called by muse, mutect2, varscan2
- RFT1 | c.1602C>G p.P534= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as COSV99965504; called by muse, mutect2, varscan2
- SWT1 | c.2682C>T p.D894= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as COSV100833417; called by muse, mutect2, varscan2
- TROAP | c.579G>A p.L193= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99226930; called by muse, mutect2, varscan2
- VWA3B | c.2961C>A p.I987= | Silent (SNP) | VAF 143/380 reads (38%) | catalogued as COSV101346090; called by muse, mutect2, varscan2
- ZNF638 | c.1164G>A p.V388= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100039309; called by muse, mutect2, varscan2
- ANKMY1 | c.-78G>T | 5'UTR (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99802602; called by muse, mutect2
